Somatic mutation profile of tumor specimen TCGA-ZJ-A8QQ-01A (aliquot TCGA-ZJ-A8QQ-01A-11D-A37N-09) from TCGA case TCGA-ZJ-A8QQ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: GX; Age at diagnosis: 24.4 years (8,918 days).
Specimen TCGA-ZJ-A8QQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 87437a68-54ee-4996-b585-2a5b703df8da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZJ-A8QQ-10A (Blood Derived Normal), aliquot TCGA-ZJ-A8QQ-10A-01D-A37N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e151f38-577b-42f4-b08f-9aeffef76d6a

The open-access MAF lists 179 somatic variants for this specimen: 134 protein-altering or splice-affecting, 44 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 111, Silent 44, Nonsense Mutation 15, Splice Region 3, Frame Shift Ins 2, Frame Shift Del 2, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABL2 | c.2999C>G p.S1000* (on ENST00000502732 / NM_007314.4; = p.S985* on NM_005158.5) | Nonsense Mutation (SNP) | VAF 12/38 reads (32%) | catalogued as COSV61016052; called by muse, mutect2, varscan2
- AC023055.1 | c.973+3G>A | Splice Region (SNP) | VAF 9/33 reads (27%) | catalogued as COSV54477828, COSV54479039; called by muse, mutect2, varscan2
- ADNP | c.2359G>T p.E787* | Nonsense Mutation (SNP) | VAF 24/32 reads (75%) | catalogued as COSV62425281, COSV62426358; called by muse, mutect2, varscan2
- ADNP | c.2189G>T p.R730L | Missense Mutation (SNP) | VAF 29/39 reads (74%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV62426366; called by muse, mutect2, varscan2
- AHNAK2 | c.12862G>T p.D4288Y | Missense Mutation (SNP) | VAF 54/135 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs900481598, COSV60917319, COSV60924217; called by muse, mutect2, varscan2
- ALDH1A2 | c.755C>G p.S252C | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); catalogued as COSV51087370; called by muse, mutect2, varscan2
- ALOX5 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as COSV65553602; called by muse, mutect2, varscan2
- AMPD1 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs773580936, COSV62417632; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.5522C>T p.S1841F | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); catalogued as rs879573902, COSV51854524; called by muse, mutect2, varscan2
- ANKRD1 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV65467117, COSV65468105; called by muse, mutect2, varscan2
- ANKRD24 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as rs774460702, COSV53673765; called by muse, mutect2
- ANKRD30A | c.1717G>A p.E573K (on ENST00000611781; = p.E517K on NM_052997.2) | Missense Mutation (SNP) | VAF 53/211 reads (25%) | SIFT tolerated (0.68); PolyPhen benign (0.026); catalogued as COSV64616693; called by muse, mutect2, varscan2
- ARSI | c.676C>G p.Q226E | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.99); PolyPhen benign (0.027); catalogued as COSV60818070; called by muse, mutect2, varscan2
- ASPM | c.5023T>C p.F1675L | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.787); catalogued as COSV54135076; called by muse, mutect2, varscan2
- AZIN1 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.049); catalogued as COSV61480903; called by muse, mutect2, varscan2
- BACH1 | c.965C>G p.S322C | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV54520233; called by muse, mutect2, varscan2
- BEGAIN | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.35); catalogued as COSV62069646; called by muse, mutect2, varscan2
- C12orf43 | c.82G>C p.E28Q | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV56566313, COSV56566816; called by muse, mutect2, varscan2
- C2orf16 | c.5131C>T p.H1711Y | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.434); catalogued as COSV62677352; called by muse, mutect2, varscan2
- CABIN1 | c.5534G>A p.R1845H | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs770625706, COSV54086599; called by muse, mutect2, varscan2
- CACNA1A | c.3880G>C p.E1294Q | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64189912; called by muse, mutect2, varscan2
- CCDC77 | c.535C>T p.Q179* | Nonsense Mutation (SNP) | VAF 16/64 reads (25%) | catalogued as COSV53474505; called by muse, mutect2, varscan2
- CD247 | c.319C>A p.Q107K (on ENST00000362089 / NM_198053.3; = p.Q106K on NM_000734.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.053); catalogued as COSV62979518; called by muse, mutect2, varscan2
- CD70 | c.202C>T p.Q68* | Nonsense Mutation (SNP) | VAF 16/49 reads (33%) | catalogued as COSV55566768; called by muse, mutect2, varscan2
- CD72 | c.752C>G p.S251* | Nonsense Mutation (SNP) | VAF 24/62 reads (39%) | catalogued as COSV52411963; called by muse, mutect2, varscan2
- CEP350 | c.6241G>C p.E2081Q | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62607398; called by muse, mutect2, varscan2
- COL19A1 | c.1484G>C p.G495A | Missense Mutation (SNP) | VAF 59/143 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV59580956, COSV59581289; called by muse, mutect2, varscan2
- COL5A3 | c.1332G>C p.M444I | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV53416161; called by muse, mutect2
- COLGALT2 | c.1205C>T p.S402F | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV62300148; called by muse, mutect2, varscan2
- CRY1 | c.1452G>A p.M484I | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.49); catalogued as COSV50487430; called by muse, mutect2, varscan2
- DCAF12L1 | c.612T>A p.S204R | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV64422449; called by muse, mutect2, varscan2
- DDX23 | c.1378G>A p.D460N | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.415); catalogued as COSV57282416, COSV57285422; called by muse, mutect2, varscan2
- DMKN | c.334G>C p.E112Q | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV60088220; called by muse, mutect2, varscan2
- DNAH12 | c.605C>T p.S202F | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as COSV60856528, COSV60858110; called by muse, mutect2, varscan2
- DOCK7 | c.5166G>C p.L1722F (on ENST00000635253 / NM_001367561.1; = p.L1691F on NM_033407.3) | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52015812, COSV52022602; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.101); catalogued as COSV50052456; called by muse, mutect2, varscan2
- EBLN2 | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.975); catalogued as COSV55597122; called by muse, mutect2, varscan2
- ERCC6L2 | c.643G>T p.E215* | Nonsense Mutation (SNP) | VAF 53/98 reads (54%) | catalogued as COSV56633106; called by muse, mutect2, varscan2
- EXD1 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV59253000; called by muse, mutect2
- EZHIP | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV57957116; called by muse, mutect2, varscan2
- FAM133A | c.161G>A p.G54D | Missense Mutation (SNP) | VAF 73/136 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.188); catalogued as rs776596033, COSV59073567, COSV59076903; called by muse, mutect2, varscan2
- FAM209B | c.385G>C p.E129Q | Missense Mutation (SNP) | VAF 36/46 reads (78%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV64915536; called by muse, mutect2, varscan2
- FAT1 | c.10679C>G p.S3560* | Nonsense Mutation (SNP) | VAF 14/22 reads (64%) | catalogued as COSV71675330; called by muse, mutect2, varscan2
- FKBP4 | c.823G>C p.E275Q | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.428); catalogued as COSV50009584; called by muse, mutect2, varscan2
- FKBP9 | c.1501G>C p.D501H | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54233253; called by muse, mutect2, varscan2
- FLNB | c.2357G>A p.R786Q | Missense Mutation (SNP) | VAF 27/38 reads (71%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.466); catalogued as rs142314034, COSV99911646; called by muse, mutect2, varscan2
- FLNC | c.3887C>T p.S1296L | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747587140, COSV57949454; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FMN2 | c.4761G>T p.L1587F | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.888); catalogued as COSV60444089; called by muse, mutect2, varscan2
- FREM2 | c.3112G>A p.D1038N | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT tolerated (0.13); PolyPhen benign (0.273); catalogued as COSV54836965, COSV54846079; called by muse, mutect2, varscan2
- FYCO1 | c.3735C>A p.S1245R | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.408); catalogued as COSV56118261; called by muse, mutect2, varscan2
- FZD6 | c.683G>C p.R228T | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62472173, COSV62472663; called by muse, mutect2, varscan2
- GIP | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.539); catalogued as COSV62467561; called by muse, mutect2, varscan2
- GPR20 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.057); catalogued as COSV66684774; called by muse, mutect2, varscan2
- GRIA2 | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.875); catalogued as COSV52394049, COSV52400205; called by muse, mutect2, varscan2
- HIVEP3 | c.2000C>G p.S667* | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | catalogued as COSV56020339; called by muse, mutect2, varscan2
- HNRNPR | c.139G>C p.D47H | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.179); catalogued as COSV56423267; called by muse, mutect2, varscan2
- IFT46 | c.379G>A p.D127N (on ENST00000264021 / NM_001168618.2; = p.D178N on NM_020153.3) | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.31); catalogued as COSV50594862; called by muse, mutect2, varscan2
- IL12A | c.277C>G p.L93V | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV59759808; called by muse, mutect2, varscan2
- INPPL1 | c.2015C>G p.A672G | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.278); catalogued as COSV53357892; called by muse, mutect2, varscan2
- IQCC | c.1267C>T p.H423Y | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.6); catalogued as COSV52210348; called by muse, mutect2, varscan2
- JAK1 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as rs758451418, COSV61094668; called by muse, mutect2, varscan2
- KDM2A | c.2238C>G p.S746R | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.482); catalogued as COSV58190907; called by muse, mutect2, varscan2
- KNTC1 | c.4321G>C p.D1441H | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV61082567; called by muse, mutect2, varscan2
- KSR1 | c.1899G>C p.K633N (on ENST00000644974 / NM_001367810.1; = p.K518N on NM_014238.2) | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52036709; called by muse, mutect2, varscan2
- LARP4 | c.1445C>T p.S482L | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV53325398; called by muse, mutect2, varscan2
- LATS1 | c.1657C>G p.Q553E | Missense Mutation (SNP) | VAF 33/52 reads (63%) | SIFT tolerated (0.09); PolyPhen benign (0.366); catalogued as COSV53596441, COSV53596746; called by muse, mutect2, varscan2
- LATS1 | c.620C>G p.S207* | Nonsense Mutation (SNP) | VAF 50/64 reads (78%) | catalogued as COSV53596475; called by muse, mutect2, varscan2
- LCOR | c.1687G>A p.D563N | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.444); catalogued as COSV53717596, COSV53719323; called by muse, mutect2, varscan2
- LMF2 | c.1885C>T p.Q629* | Nonsense Mutation (SNP) | VAF 21/80 reads (26%) | catalogued as COSV53318510; called by muse, mutect2, varscan2
- LNX2 | c.93G>A p.W31* | Nonsense Mutation (SNP) | VAF 9/19 reads (47%) | catalogued as COSV60337482; called by muse, mutect2, varscan2
- MAGEA8 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs1415137949, COSV54064703, COSV99674785; called by muse, mutect2, varscan2
- MAP3K9 | c.2522C>G p.S841C (on ENST00000554752 / NM_001284230.1; = p.S855C on NM_033141.4) | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV67122371; called by muse, mutect2, varscan2
- MED12 | c.1348G>C p.G450R | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV61350198; called by muse, mutect2, varscan2
- MEGF11 | c.884G>C p.G295A | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56557102; called by muse, mutect2, varscan2
- MYT1L | c.1667G>A p.R556H | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs746083137, COSV67714781; called by muse, varscan2
- NALCN | c.170C>T p.T57M | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1188144130, COSV51918402, COSV99216118; called by muse, mutect2, varscan2
- NDUFB7 | c.361G>C p.E121Q | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV53108757; called by muse, mutect2, varscan2
- NDUFV1 | c.812C>G p.S271* | Nonsense Mutation (SNP) | VAF 24/66 reads (36%) | catalogued as COSV59596161; called by muse, mutect2, varscan2
- NIN | c.4657G>C p.E1553Q (on ENST00000382041 / NM_182946.1; = p.E840Q on NM_016350.4) | Missense Mutation (SNP) | VAF 49/164 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV55400384; called by muse, mutect2, varscan2
- NIT1 | c.859G>C p.E287Q | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as COSV63502419; called by muse, mutect2, varscan2
- NMI | c.457G>C p.E153Q | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.019); catalogued as COSV54638726; called by muse, mutect2, varscan2
- NOL8 | c.879G>C p.K293N | Missense Mutation (SNP) | VAF 36/48 reads (75%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62636723; called by muse, mutect2, varscan2
- NR2C1 | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV58011540; called by muse, mutect2, varscan2
- PAX4 | c.131C>G p.S44* | Nonsense Mutation (SNP) | VAF 17/38 reads (45%) | catalogued as COSV100490274, COSV58390265; called by muse, mutect2, varscan2
- PCDHGA1 | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.506); catalogued as rs747495549, COSV100966028, COSV65297976; called by muse, mutect2, varscan2
- PDPK1 | c.191C>T p.S64F | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as COSV51914029; called by muse, mutect2, varscan2
- PKHD1L1 | c.3634G>A p.E1212K | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.872); catalogued as rs1220997412, COSV65749019; called by muse, mutect2, varscan2
- PKLR | c.128G>C p.S43T | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as COSV61361971; called by muse, mutect2, varscan2
- PLEC | c.3805C>G p.L1269V (on ENST00000322810 / NM_201380.4; = p.L1159V on NM_000445.5) | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as rs1554708777, COSV59672423; called by muse, mutect2, varscan2
- PLEKHO2 | c.1051G>C p.E351Q | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as rs1363048166, COSV60262642; called by muse, mutect2, varscan2
- POLR1G | c.1044G>C p.E348D | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.456); catalogued as COSV50004973; called by muse, mutect2, varscan2
- PPM1E | c.1525C>G p.Q509E | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); catalogued as COSV57575925, COSV57577713; called by muse, mutect2, varscan2
- PRAMEF2 | c.107A>G p.Y36C | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV53577740; called by muse, mutect2, varscan2
- PRDM2 | c.1450C>T p.P484S | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV52444575; called by muse, mutect2, varscan2
- PSIP1 | c.452G>A p.R151K | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.931); catalogued as COSV66255306; called by muse, mutect2, varscan2
- RIOK1 | c.1465C>G p.Q489E | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV53573100; called by muse, mutect2, varscan2
- RNF185 | c.339G>C p.Q113H | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.948); catalogued as COSV56736386; called by muse, mutect2, varscan2
- RTL9 | c.3362C>T p.S1121L | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as rs771130284, COSV71825811; ClinVar: uncertain significance; called by muse, mutect2
- RUBCNL | c.1596C>G p.I532M | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.45); catalogued as COSV59792238; called by muse, mutect2, varscan2
- SCAPER | c.2822G>C p.R941T | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV57748318; called by muse, mutect2, varscan2
- SEL1L3 | c.1697G>A p.C566Y | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53546530; called by muse, mutect2, varscan2
- SI | c.2167G>A p.E723K | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.039); catalogued as COSV52286091; called by muse, mutect2, varscan2
- SIPA1L2 | c.4984G>C p.E1662Q | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53396007, COSV99479564; called by muse, mutect2, varscan2
- SLC10A4 | c.843C>G p.F281L | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.621); catalogued as COSV56719474; called by muse, mutect2, varscan2
- SLC37A4 | c.44C>T p.S15L | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1555191883, COSV58155923; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLFN13 | c.2573C>T p.S858L | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV53193890; called by muse, mutect2, varscan2
- SMC6 | c.1810G>C p.D604H | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61177031; called by muse, mutect2, varscan2
- SMIM14 | c.153C>G p.I51M | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.185); catalogued as COSV55904985; called by muse, mutect2, varscan2
- SPATA16 | c.354G>C p.K118N | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.189); catalogued as rs1379670849, COSV63531737; called by muse, mutect2, varscan2
- SRPK2 | c.136G>C p.E46Q | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.954); catalogued as rs1466837511, COSV61963170; called by muse, mutect2, varscan2
- SVEP1 | c.1987G>C p.E663Q | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.335); catalogued as COSV57043388, COSV57044759; called by muse, mutect2, varscan2
- SVIL | c.121C>G p.R41G | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780503821, COSV63446325; called by muse, mutect2, varscan2
- TEP1 | c.1699C>G p.L567V | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52990784; called by muse, mutect2, varscan2
- TESK2 | c.1324G>A p.D442N | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV59155713; called by muse, mutect2, varscan2
- THRA | c.1175C>T p.S392L | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as COSV52845076; called by muse, mutect2, varscan2
- TP53BP1 | c.4083G>C p.L1361= | Splice Region (SNP) | VAF 10/36 reads (28%) | catalogued as COSV99779729; called by muse, mutect2, varscan2
- TRIP11 | c.1744G>A p.E582K | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as COSV50944006; called by muse, mutect2, varscan2
- TRPC4AP | c.2282G>A p.W761* | Nonsense Mutation (SNP) | VAF 10/20 reads (50%) | catalogued as COSV52682724; called by muse, mutect2, varscan2
- TSGA13 | c.613C>G p.Q205E | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT tolerated (0.09); PolyPhen benign (0.094); catalogued as COSV58405158, COSV58406330; called by muse, mutect2, varscan2
- UPF2 | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.074); catalogued as COSV62657763, COSV62661081, COSV62662581; called by muse, mutect2, varscan2
- USF3 | c.4312C>G p.L1438V | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV57075769; called by muse, mutect2, varscan2
- VCAN | c.3923C>G p.S1308C | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54112473; called by muse, mutect2, varscan2
- XPO7 | c.883T>C p.F295L | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.88); catalogued as COSV53018197; called by muse, mutect2, varscan2
- ZNF423 | c.1374G>A p.M458I (on ENST00000563137 / NM_001379286.1; = p.M450I on NM_015069.4) | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as COSV52199156; called by muse, mutect2, varscan2
- ZNF48 | c.1051C>T p.R351C | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1041739800, COSV100198284, COSV60783181; called by muse, mutect2, varscan2
- ZNF536 | c.1919T>C p.F640S | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62830403; called by muse, mutect2, varscan2
- ZNF548 | c.1355G>C p.R452T | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as rs1389942122, COSV60241136, COSV60241609; called by muse, mutect2, varscan2
- ZNF766 | c.1019C>G p.S340* | Nonsense Mutation (SNP) | VAF 17/46 reads (37%) | catalogued as COSV63009999; called by muse, mutect2, varscan2
- ARHGAP4 | c.1137G>A p.V379= | Splice Region (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2
- MTR | c.1122_1123insTCATT p.G375Sfs*50 | Frame Shift Ins (INS) | VAF 12/54 reads (22%) | called by mutect2, pindel, varscan2
- P3H3 | c.1929_1959del p.R644Ifs*8 | Frame Shift Del (DEL) | VAF 7/49 reads (14%) | called by mutect2, pindel
- POLR1G | c.1275_1276del p.K426Efs*10 | Frame Shift Del (DEL) | VAF 16/42 reads (38%) | called by muse*, mutect2, varscan2*
- TRPM2 | c.1297_1308del p.I433_A436del | In Frame Del (DEL) | VAF 10/35 reads (29%) | called by mutect2, pindel, varscan2
- YIPF5 | c.319dup p.T107Nfs*18 | Frame Shift Ins (INS) | VAF 32/92 reads (35%) | called by mutect2, pindel, varscan2
- ABCC3 | c.1395C>G p.L465= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV53326406; called by muse, mutect2, varscan2
- ADAMTS14 | c.3117G>A p.T1039= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs368301219, COSV100941647, COSV64604833; called by muse, mutect2
- ARF1 | c.249G>A p.Q83= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as COSV55255569; called by muse, mutect2, varscan2
- ASZ1 | c.6G>A p.A2= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as COSV52915195; called by muse, mutect2, varscan2
- ATG16L2 | c.1455C>A p.I485= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV100352152; called by muse, mutect2, varscan2
- CABP2 | c.585C>T p.D195= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as rs753451816, COSV53709378; called by muse, mutect2, varscan2
- CABP4 | c.708G>A p.P236= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as rs550153300, COSV57799216; called by muse, mutect2, varscan2
- CAPN6 | c.1491G>A p.L497= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as rs1392926490, COSV60694352; called by muse, mutect2, varscan2
- CCT3 | c.438C>A p.I146= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV55290580; called by muse, mutect2
- CDC42BPB | c.4080G>A p.T1360= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as rs760866818, COSV100775157; called by muse, mutect2, varscan2
- CHD6 | c.1038G>A p.Q346= | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as COSV100497721; called by muse, mutect2, varscan2
- CLTC | c.4512C>T p.L1504= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV52250396; called by muse, mutect2, varscan2
- CORO1A | c.348G>C p.L116= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV54631837; called by muse, mutect2, varscan2
- DHTKD1 | c.2514C>T p.L838= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV53805576; called by muse, mutect2, varscan2
- EXD1 | c.1197G>A p.E399= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as COSV59255632; called by muse, mutect2
- GRIA3 | c.213G>A p.L71= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs746428230, COSV52053253; called by mutect2, varscan2
- HIVEP2 | c.3438G>T p.L1146= | Silent (SNP) | VAF 22/34 reads (65%) | catalogued as COSV50034084; called by muse, mutect2, varscan2
- HLX | c.138C>T p.I46= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs752408913, COSV65045350; called by muse, mutect2, varscan2
- IGLV4-3 | c.69G>A p.L23= | Silent (SNP) | VAF 11/28 reads (39%) | called by muse, mutect2, varscan2
- INTS1 | c.258G>A p.L86= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as COSV67178654; called by muse, mutect2, varscan2
- KDM4C | c.2475C>T p.I825= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV67190025; called by muse, mutect2, varscan2
- KRT72 | c.237C>T p.F79= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV53376064; called by muse, mutect2, varscan2
- KSR2 | c.2475G>A p.Q825= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV56679473; called by muse, mutect2, varscan2
- LAIR1 | c.558C>G p.L186= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as COSV57308951; called by muse, mutect2, varscan2
- LHX6 | c.312G>A p.L104= (on ENST00000373755 / NM_001242334.2; = p.L133= on NM_014368.5) | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as COSV61344479; called by muse, mutect2, varscan2
- MPL | c.1275C>G p.L425= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV65246112; called by muse, mutect2, varscan2
- MSH5 | c.1038G>C p.L346= | Silent (SNP) | VAF 36/45 reads (80%) | catalogued as COSV65210736, COSV65210830; called by muse, mutect2, varscan2
- NDFIP2 | c.300G>A p.P100= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as rs1025277242; called by muse, mutect2
- NLRP13 | c.261C>A p.G87= | Silent (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- OAS3 | c.2574C>T p.V858= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV99966013; called by muse, mutect2, varscan2
- OR52E2 | c.192C>T p.F64= | Silent (SNP) | VAF 35/58 reads (60%) | catalogued as rs769187663, COSV58613152; called by muse, mutect2, varscan2
- OSBPL5 | c.1053G>C p.L351= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV55144270; called by muse, mutect2, varscan2
- PAFAH1B1 | c.360C>T p.F120= | Silent (SNP) | VAF 22/37 reads (59%) | catalogued as COSV68210462; called by muse, mutect2, varscan2
- PCBP1 | c.399G>A p.V133= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as COSV57851573; called by muse, mutect2, varscan2
- RMI1 | c.1851G>A p.E617= | Silent (SNP) | VAF 24/92 reads (26%) | catalogued as COSV57936905, COSV57937245; called by muse, mutect2, varscan2
- RPL36A | c.81G>A p.K27= | Silent (SNP) | VAF 30/134 reads (22%) | catalogued as COSV100864945; called by muse, mutect2, varscan2
- SLC10A3 | c.189C>G p.G63= | Silent (SNP) | VAF 23/103 reads (22%) | catalogued as COSV54836971; called by muse, mutect2, varscan2
- SLC24A2 | c.102G>A p.L34= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV53871251; called by muse, mutect2, varscan2
- SRPK3 | c.153C>T p.D51= | Silent (SNP) | VAF 43/103 reads (42%) | catalogued as rs376305455, COSV99472928; ClinVar: likely benign; called by muse, mutect2, varscan2
- TAF3 | c.957G>A p.K319= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as rs1183699157, COSV60209658; called by muse, mutect2, varscan2
- TOR1B | c.558C>T p.I186= | Silent (SNP) | VAF 24/92 reads (26%) | catalogued as COSV52214219, COSV99399998; called by muse, varscan2
- TYRP1 | c.285C>T p.F95= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV66358243; called by muse, mutect2, varscan2
- ZNF627 | c.249C>T p.F83= | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as COSV63142698; called by muse, mutect2, varscan2
- ZNF830 | c.348G>A p.A116= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV58490823; called by muse, mutect2, varscan2
- C5orf64 | n.512+52084C>G | Intron (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2
